Somatic mutation profile of tumor specimen TARGET-20-PATDNN-04A (aliquot TARGET-20-PATDNN-04A-01D) from TARGET case TARGET-20-PATDNN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,262 days).
Specimen TARGET-20-PATDNN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ee3d655-f730-4e46-9bc5-2fbf02a84c7a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDNN-10A (Blood Derived Normal), aliquot TARGET-20-PATDNN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2d05e1-b172-4706-8296-6e8c33c54d43

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 51/169 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.5696_5697insC p.E1899Dfs*12 | Frame Shift Ins (INS) | VAF 70/291 reads (24%) | catalogued as COSV57449093; called by mutect2, pindel, varscan2
